Gene-level copy-number profile of tumor specimen TCGA-R5-A7O7-01A from TCGA case TCGA-R5-A7O7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.0 years (18,984 days).
Specimen TCGA-R5-A7O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3d453158-c8de-4941-b1df-cd6d74f645f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R5-A7O7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/efc4434f-91b4-455d-bcd2-981b99e32e38

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 8; copy number 2: 6,955; copy number 3: 31,629; copy number 4: 10,973; copy number 5: 5,678; copy number 6: 2,195; copy number 7: 1,035; copy number 8: 188; copy number 9: 77; copy number 10: 110; copy number 11: 86; copy number 12: 13; copy number 13: 112; copy number 14: 6; copy number 16: 135; copy number 17: 2; copy number 18: 101; copy number 20: 27; copy number 23: 64; copy number 25: 98; copy number 28: 4; copy number 29: 25; copy number 33: 27; copy number 34: 13; copy number 35: 72; copy number 37: 16; copy number 44: 3; copy number 49: 27; copy number 69: 19; copy number 71: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R5-A7O7-01A-11D-A33S-01): tumor purity 0.2, ploidy 3.87, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr8:6,044,353–6,708,224, 9 genes (within-gene range 0–2): AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055.
- chr8:8,228,595–8,895,918, 15 genes (within-gene range 0–13): FAM86B3P, ALG1L13P, PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, AC087269.3, CLDN23, AC087269.2, AC087269.1, MFHAS1, RNU6-682P.
- chr8:12,356,136–15,238,431, 54 genes (within-gene range 0–2): ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, AC068587.8, AC068587.6, RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,298 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,106,016–87,196,629, 160 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:105,600,703–106,194,301, 8 genes, copy number 23: AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1.
- chr2:218,125,289–218,702,716, 29 genes, copy number 8 (within-gene range 4–8): CXCR2, CXCR1, HMGB1P9, ARPC2, AC021016.1, GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P, PLCD4, ZNF142, BCS1L, RNF25, STK36.
- chr3:14,920,347–14,948,424, 1 gene, copy number 12: FGD5-AS1.
- chr3:19,148,510–22,373,321, 21 genes, copy number 8–44 (within-gene range 2–44): KCNH8, MIR4791, AC061958.1, EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18, KAT2B, MIR3135A, SGO1, SGO1-AS1, RNU6-822P, AC116096.1, RNU6-815P, AC099753.1, VENTXP7, ZNF385D, ZNF385D-AS1.
- chr3:31,657,890–32,786,116, 27 genes, copy number 33: OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43.
- chr3:33,956,972–34,694,174, 5 genes, copy number 37: LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1.
- chr3:55,508,311–56,468,467, 1 gene, copy number 10 (within-gene range 2–15): ERC2.
- chr3:55,852,492–55,852,594, 1 gene, copy number 10: MIR3938.
- chr3:56,557,161–57,170,306, 8 genes, copy number 25: CCDC66, TASOR, ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1.
- chr3:70,959,226–71,754,229, 1 gene, copy number 37 (within-gene range 2–37): AC097634.4.
- chr3:71,541,970–72,279,503, 19 genes, copy number 25–37 (within-gene range 2–37): MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1.
- chr4:70,848,136–78,544,269, 131 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:218,241–1,551,710, 50 genes, copy number 23: SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2.
- chr5:2,921,496–4,041,764, 9 genes, copy number 17–25: AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1.
- chr5:10,664,495–21,341,375, 129 genes, copy number 10–34 (within-gene range 2–34) (broad region; genes not listed).
- chr5:23,262,159–45,895,970, 334 genes, copy number 7–35 (broad region; genes not listed).
- chr6:38,168,451–43,737,834, 158 genes, copy number 7–11 (broad region; genes not listed).
- chr7:15,200,317–34,878,332, 347 genes, copy number 7–29 (within-gene range 5–29) (broad region; genes not listed).
- chr7:45,859,994–53,188,938, 81 genes, copy number 11–18 (within-gene range 5–18) (broad region; genes not listed).
- chr7:100,307,702–108,130,361, 212 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:6,808,517–8,226,614, 107 genes, copy number 13 (broad region; genes not listed).
- chr8:10,433,672–12,333,693, 84 genes, copy number 49–71 (broad region; genes not listed).
- chr10:26,379,034–35,231,394, 173 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr10:35,250,959–35,251,052, 1 gene, copy number 7: RNU6-1167P.
- chr13:18,467,172–19,783,019, 52 genes, copy number 8 (within-gene range 4–8): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1.
- chr13:30,340,267–32,911,650, 47 genes, copy number 8–9: LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423.
- chr18:20,946,906–24,402,714, 79 genes, copy number 7–11 (broad region; genes not listed).
- chr19:29,775,504–31,349,436, 23 genes, copy number 7–16 (within-gene range 2–16): AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
